Surgical pathology report (de-identified scan), TCGA case TCGA-B7-5818, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Cureline, specimen TCGA-B7-5818-01A (Primary Tumor).

[page 1 of 4]
Index	Specimen label	Clinical Site #	Case #	Ethnicity (Race)	Clinical Diagnosis	DOB (mm/dd/yyyy)	Sex	Date of procurement
1					Gastric cancer			
					Gastric cancer			

[page 2 of 4]
Anatomical Site	Tumor Location	Tissue Specification	Specimen Matrix	Specimen Format	Container	Number of containers	Amount/per container	Unit
Stomach, body	Primary	Tumor	Tissue	Frozen	cryomold	1	340	mg
Blood	n/a	normal	Blood	Frozen	tube	1	4	ml

[page 3 of 4]
Type of Procurement	Histological description	Grade	TNM Stage (T)	TNM Stage (N)	TNM Stage (M)	Prior Chemo / Hormonal Th	Chemo / Horm Th Details	Prior Radiation
Surgery	Adenocarcinoma	no data	no data	no data	no data	no	no	no
Blood draw	n/a	n/a	n/a	n/a	n/a	no	no	no

[page 4 of 4]
[REDACTED]

[REDACTED]

[REDACTED]

Cellular Tumor %
70
n/a

Source: NCI Genomic Data Commons file 4217af1d-85ba-461d-ba1f-cf09ddcde84e (TCGA-B7-5818.E8C3173E-5CF2-4CC1-85FA-7D0721E90BD0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).